FM case AD3523 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/8cb733c4-fb74-4b9e-80f2-1cfd69dde929

Female, 51.7 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the appendix. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
